Somatic mutation profile of tumor specimen ALCH-B0DQ-TTP1-A (aliquot ALCH-B0DQ-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0DQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.2 years (19,791 days).
Specimen ALCH-B0DQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 546926bf-4c7e-412d-b1bb-9b22665ef4b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DQ-NB1-A (Blood Derived Normal), aliquot ALCH-B0DQ-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e5f1c48-43e3-433f-98c2-3a12700a664a

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 36/270 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- DCAF4L2 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs748067917, COSV100151225, COSV60479829; called by muse, mutect2, varscan2
- DHX8 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs199963654, COSV52257050; called by muse, mutect2, varscan2
- FAT3 | c.2521C>A p.L841I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as COSV53084162; called by muse, mutect2, varscan2
- KCNF1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54461978; called by muse, mutect2
- SMAD2 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50992958; called by muse, varscan2
- USP11 | c.2189G>A p.R730H (on ENST00000218348; = p.R687H on NM_001371072.1) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.938); catalogued as rs1223922759, COSV54473479; called by muse, mutect2, varscan2
- ZBED9 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as rs866662971, COSV71729876; called by muse, mutect2
- ZNF229 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 14/151 reads (9%) | catalogued as rs773316062, COSV52160583; called by muse, mutect2
- KDM2B | c.1855T>C p.C619R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM1 | c.4605G>T p.Q1535H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TNPO2 | c.1819C>T p.Q607* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- UBR5 | c.4316T>A p.L1439Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR7 | c.2383T>G p.L795V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF280B | c.1613_1616delinsAAAA p.I538_S539delinsKK | Missense Mutation (ONP) | VAF 4/22 reads (18%) | called by muse*, mutect2*, pindel
- BEST3 | c.984C>T p.S328= | Silent (SNP) | VAF 30/238 reads (13%) | catalogued as rs1435612516; called by muse, mutect2, varscan2
- CNGB3 | c.2283T>C p.I761= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- MACROD2 | c.366C>A p.G122= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV53988615; called by muse, mutect2, varscan2
- MFSD13A | c.1161C>T p.D387= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs750592175; called by mutect2, varscan2
- MYT1 | c.1137C>T p.G379= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- NLRP7 | c.1080C>A p.G360= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs199475825; ClinVar: not provided; called by muse, mutect2, varscan2
- PCDH18 | c.1365C>T p.I455= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100787148, COSV100787585; called by muse, mutect2, varscan2
- ZCCHC10 | c.107+3784A>G | Intron (SNP) | VAF 15/109 reads (14%) | catalogued as rs1429733375; called by muse, mutect2, varscan2
